Somatic mutation profile of tumor specimen C3N-01526-01 (aliquot CPT0096010009) from CPTAC case C3N-01526, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 66.4 years (24,258 days).
Specimen C3N-01526-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10123484-59b5-42b1-ab20-b2f384252b9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01526-31 (Blood Derived Normal), aliquot CPT0096050002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/591545ec-e96e-459f-89a4-9d8f51833501

The open-access MAF lists 54 somatic variants for this specimen: 37 protein-altering or splice-affecting, 12 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 12, Frame Shift Del 4, Nonsense Mutation 3, Frame Shift Ins 2, 5'UTR 2, 5'Flank 1, Intron 1, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.2974C>T p.Q992* | Nonsense Mutation (SNP) | VAF 450/591 reads (76%) | catalogued as rs1135401825; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CTNNB1 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 207/531 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913403, COSV62687856, COSV62688281, COSV62689256; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 76/176 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 406/536 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CWC22 | c.958C>T p.R320* | Nonsense Mutation (SNP) | VAF 128/305 reads (42%) | catalogued as rs775503494, COSV104404189; called by muse, mutect2, varscan2
- CYP4F12 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 160/419 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.207); catalogued as rs1263415539, COSV61175126; called by muse, mutect2, varscan2
- E4F1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 140/376 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs140445968; called by muse, mutect2, varscan2
- FAM20C | c.1673G>A p.R558Q | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.035); catalogued as rs562265099; called by muse, mutect2
- HNF1A | c.832C>T p.R278W | Missense Mutation (SNP) | VAF 208/608 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1344788314, COSV57462558; called by muse, mutect2, varscan2
- KNDC1 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 153/187 reads (82%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as rs746222106; called by muse, mutect2, varscan2
- MMP9 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 197/443 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201191171, COSV63433971; called by muse, mutect2, varscan2
- MROH8 | c.815G>A p.G272D | Missense Mutation (SNP) | VAF 70/209 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.106); catalogued as COSV54124592; called by muse, mutect2, varscan2
- OR6C70 | c.221C>T p.A74V | Missense Mutation (SNP) | VAF 64/141 reads (45%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756519489; called by muse, mutect2, varscan2
- PAX8 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 109/268 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751837678; called by muse, mutect2, varscan2
- PCIF1 | c.1884-4G>A | Splice Region (SNP) | VAF 88/232 reads (38%) | catalogued as rs766421922; called by muse, mutect2, varscan2
- PIWIL1 | c.247C>T p.R83C | Missense Mutation (SNP) | VAF 91/263 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1331871061, COSV55350040, COSV55351334; called by muse, mutect2, varscan2
- PXDN | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 125/354 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53226287; called by muse, mutect2, varscan2
- RIPOR2 | c.2683G>C p.G895R | Missense Mutation (SNP) | VAF 52/146 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as rs140410062; called by muse, mutect2, varscan2
- SLC26A3 | c.1298C>T p.A433V | Missense Mutation (SNP) | VAF 186/519 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as rs200724013, COSV60643320; called by muse, mutect2, varscan2
- SNCAIP | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774945324, COSV54422922; called by muse, mutect2, varscan2
- SNX13 | c.454G>A p.D152N | Missense Mutation (SNP) | VAF 48/108 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1270347963, COSV101285136; called by muse, mutect2, varscan2
- TEP1 | c.4082G>A p.R1361Q | Missense Mutation (SNP) | VAF 85/281 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs778056728; called by muse, mutect2, varscan2
- XIRP2 | c.8869C>T p.R2957* (on ENST00000628543; = p.R3132* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 102/276 reads (37%) | catalogued as rs779443993, COSV54716024; called by muse, mutect2, varscan2
- ZNF730 | c.494_498del p.I165Tfs*10 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs765829830; called by pindel, varscan2
- ADSL | c.1402dup p.L468Pfs*6 | Frame Shift Ins (INS) | VAF 166/536 reads (31%) | called by mutect2, pindel, varscan2
- ARID5B | c.1301del p.N434Tfs*45 | Frame Shift Del (DEL) | VAF 125/394 reads (32%) | called by mutect2, pindel, varscan2
- ATF7IP | c.548_552del p.D183Vfs*4 | Frame Shift Del (DEL) | VAF 139/464 reads (30%) | called by mutect2, pindel, varscan2
- COMMD9 | c.22C>G p.H8D | Missense Mutation (SNP) | VAF 60/205 reads (29%) | SIFT tolerated (0.62); PolyPhen benign (0); called by muse, mutect2, varscan2
- JPH1 | c.473C>G p.P158R | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MTOR | c.4170C>G p.C1390W | Missense Mutation (SNP) | VAF 126/331 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- NLRC5 | c.4216G>T p.A1406S | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1604_1610del p.G535Efs*46 (on ENST00000259318 / NM_001136562.3; = p.G766Efs*46 on NM_007203.5) | Frame Shift Del (DEL) | VAF 95/239 reads (40%) | called by pindel, varscan2*
- PAXBP1 | c.1500C>A p.S500R | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- PCNX2 | c.1715dup p.N572Kfs*2 | Frame Shift Ins (INS) | VAF 97/306 reads (32%) | called by mutect2, pindel, varscan2
- PIF1 | c.478C>G p.L160V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SGCZ | c.825T>A p.S275R | Missense Mutation (SNP) | VAF 64/205 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- ZC3HAV1 | c.2198T>G p.I733S | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- AJAP1 | c.244C>A p.R82= | Silent (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2, varscan2
- BMX | c.1200C>T p.P400= | Silent (SNP) | VAF 71/205 reads (35%) | catalogued as rs201999800, COSV59591362; called by muse, mutect2, varscan2
- COL11A1 | c.4278C>T p.G1426= | Silent (SNP) | VAF 80/228 reads (35%) | called by muse, mutect2, varscan2
- DGCR8 | c.2280C>T p.S760= | Silent (SNP) | VAF 97/252 reads (38%) | catalogued as rs374499450; called by muse, mutect2, varscan2
- FAM9A | c.954T>C p.N318= | Silent (SNP) | VAF 61/160 reads (38%) | called by muse, mutect2, varscan2
- FARSA | c.970C>T p.L324= | Silent (SNP) | VAF 132/396 reads (33%) | called by muse, mutect2, varscan2
- MED16 | c.1425C>T p.L475= | Silent (SNP) | VAF 133/389 reads (34%) | catalogued as rs191791872; called by muse, mutect2, varscan2
- PREX1 | c.3729G>A p.R1243= | Silent (SNP) | VAF 160/402 reads (40%) | catalogued as COSV64248730; called by muse, mutect2, varscan2
- TPTE | c.870C>T p.Y290= (on ENST00000618007 / NM_199261.4; = p.Y272= on NM_199259.4) | Silent (SNP) | VAF 74/463 reads (16%) | catalogued as rs571858375; called by muse, mutect2, varscan2
- TRIM72 | c.1218C>T p.P406= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as rs763684056, COSV59069397; called by muse, mutect2, varscan2
- TTLL3 | c.1572C>T p.S524= | Silent (SNP) | VAF 95/252 reads (38%) | called by muse, mutect2, varscan2
- VPS13B | c.1764C>T p.S588= | Silent (SNP) | VAF 105/312 reads (34%) | called by muse, mutect2, varscan2
- DIAPH2 | c.-16A>T | 5'UTR (SNP) | VAF 9/25 reads (36%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899639 C>T | 3'Flank (SNP) | VAF 137/499 reads (27%) | called by muse, mutect2, varscan2
- MGP | c.62-642G>A | Intron (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- PMM1 | c.-1C>T | 5'UTR (SNP) | VAF 65/169 reads (38%) | called by muse, mutect2, varscan2
- RBM34 | chr1:235161333 del CCGGGCGGCGGCGAA | 5'Flank (DEL) | VAF 31/118 reads (26%) | called by mutect2, pindel, varscan2
